Surgical pathology report (de-identified scan), TCGA case TCGA-RN-A68Q, project TCGA-SARC (Sarcoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RN-A68Q-01A (Primary Tumor).

Tumor ID

ICD-O-3
Tumor, peripheral nerve
sheath, malignant 9540/3
Site: Dura, lumbar c70.1
9/26/28/13

Microscopic Description:

Sections demonstrate a markedly hypercellular spindle cell neoplasm in a fibrous stroma. Tumor cells demonstrate only mild cytologic atypia. There is a rare focus of necrosis seen. Scattered mitotic figures are seen with up to 3 mitoses per 10 high power fields. The neoplastic cells are immunoreactive for S-100 but negative for EMA and CD-34. MIB-1 labeling is patchy with large areas with <5% positivity, but multiple smaller foci with a labeling index of up to 50%. Overall, the findings are more consistent with a malignant peripheral nerve sheath tumor, with the intratumor variability in cellularity, atypia and proliferative activity suggesting recent transformation from a benign neurofibroma. However, a spindle cell melanoma remains to be excluded by additional special stains.

Diagnosis:

Lumbar Intradural Tumor-

Malignant spindle cell neoplasm, most consistent with malignant peripheral nerve sheath tumor.

Addendum Discussion:

There is a high background positivity for the melanoma cocktail antibody, but the core cells, themselves, are negative.

HI-AA Discrepancy		1/1

Source: NCI Genomic Data Commons file 390f7429-5fa1-4e5a-bc71-722d493922c3 (TCGA-RN-A68Q.E203AF5D-029B-4EB8-9133-B0427709D3DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).